Surgical pathology report (de-identified scan), TCGA case TCGA-30-1861, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1861-01A (Primary Tumor).

[page 1 of 2]
Accession Number: [REDACTED] Report Status: Final
Type: Surgical Pathology
Pathology Report [REDACTED] TISSUE FOR SPECIAL STUDIES ONLY
Accessioned On: [REDACTED]

DIAGNOSIS: [REDACTED]

SPECIMEN LABELED "RECTUS MUSCLE":

Tissue entirely submitted for special studies from frozen section lab.

TCGA-30-1861

SPECIMEN LABELED "OMENTAL TUMOR" (including frozen section A):
METASTATIC ADENOCARCINOMA.

SPECIMEN LABELED "RIGHT ADNEXAL TUMOR" (including frozen section B):
PAPILLARY SEROUS ADENOCARCINOMA, grade 3 (of 3) - periovarian mass.

SPECIMEN LABELED "ADDITIONAL RIGHT ADNEXAL TUMOR":
METASTATIC ADENOCARCINOMA in fallopian tube and on surface of atrophic
ovary with ovarian lymphovascular invasion.

SPECIMEN LABELED "LEFT TUBE AND OVARY WITH TUMOR":
PAPILLARY SEROUS ADENOCARCINOMA grade 3 of 3, periovarian mass with
metastases to fallopian tube and surface of atrophic ovary.

SPECIMEN LABELED "UTERUS AND CERVIX" (17gm):
Cervix:
METASTATIC ADENOCARCINOMA in paracervical soft tissue.

Endometrium:
Inactive endometrium.

Myometrium:
Leiomyomata (1.0 cm).

Serosa:
METASTATIC ADENOCARCINOMA.

SPECIMEN LABELED "TUMOR FROM CUL DE SAC":
METASTATIC ADENOCARCINOMA.

CLINICAL DATA:

History: [REDACTED] with ascites, increased CA125 and peritoneal nodules.
Operation: TAH/BSO, omental biopsy
Clinical Diagnosis: ?Ovarian cancer

TISSUE SUBMITTED: 1. Rectus muscle (for research)
2. Omental tumor (FS)
3. Right adnexal tumor (FS)
4. Additional right adnexal tumor
5. Left tube and ovary with tumor
6. Uterus and cervix
7. Tumor from cul-de-sac

O.R. CONSULTATION:

SPECIMEN LABELED "#2 OMENTAL TUMOR" (FSA):
Metastatic poorly differentiated carcinoma.

SPECIMEN LABELED "#3 RIGHT ADNEXAL MASS" (FSB):
Poorly differentiated carcinoma, consistent with papillary serous
carcinoma.

GROSS DESCRIPTION: [REDACTED]

The specimen is received fresh, in 7 parts, each labeled with the patient's
name and unit number.

Part 1, "rectus muscle", consists of a single fragment of red/tan muscle (2.5 x
1.4 x 0.6 cm). The entire specimen was submitted for special studies from the
frozen section lab.

Part 2, "omental tumor - [REDACTED]" consists of a single piece of fibroadipose tissue

[page 2 of 2]
(3.0 x 2.0 x 0.5 cm) with a 0.8 cm white, firm nodule. Representative sections of the nodule were submitted as "FSA".

Micro 1 - FSA remnant, 1 frag,
Micro 2 - omental tumor, 1 frag,

TCGA-30-1861

Part 3, "right adnexal mass", consists of a firm, white, ovoid mass (7.0 x 2.5 x 3.0 cm) with a focally granular surface and soft, white, solid interior. No areas of hemorrhage or focal necrosis are seen within the ovoid mass. Additionally, several fragments of blood clot and soft tissue, ranging in size from 2.5 x 0.4 x 0.4 cm up to 4.0 x 2.0 x 0.6 cm were present. Representative sections of the ovoid mass were submitted as "FSB" and additional tissue was sent to the tissue bank for special studies from the frozen section lab.

Micro 3 - FSB remnant, 1 frag,
Micro 4-5 - tumor, 2 frags

Part 4, "additional right adnexal tumor", consists of a pink/tan, fimbriated fallopian tube (3.5 cm in length by 0.5 cm in diameter) and an attached ovary (2.0 x 1.8 x 0.7 cm). The surface of the ovary is white and smooth with a single clear fluid-filled cyst. No tumor is grossly visible on either the ovary or the fallopian tube. The entire specimen is submitted for histologic evaluation.

Micro 6-7 - right fallopian tube, multiple frags,
Micro 8-9 - right ovary, multiple frags,

Part 5, "left tube and ovary with tumor", consists of a brown/tan segment of fimbriated fallopian tube (3.0 cm in length by 0.6 cm in diameter) with an attached ovary (1.7 x 0.9 x 0.4 cm). Also firmly attached to the fallopian tube is a white/tan, firm nodule (3.0 x 2.5 x 2.0 cm). The tumor is grossly similar to that submitted in part 3. Representative sections of tumor and associated adnexal structures are submitted for histologic evaluation.

Micro 10 - tumor & associated soft tissue, 1 frag,
Micro 11-13 - fallopian tube, multiple frags,
Micro 14 - ovary, multiple frags,

Part 6, "uterus and cervix", consists of a 17g uterus and attached cervix (5.4 x 3.5 x 2.4 cm). The exocervix (1.7 x 1.5 cm) has a smooth, glistening mucosal surface with a 0.4 cm external os. The endocervix (1.2 cm in length by 0.4 cm in width) has a smooth, tan herringbone-like mucosal surface. The endometrial cavity (1.0 cm from cornu to cornu by 2.3 cm in length by 0.2 cm in thickness) is tan/brown and smooth and is distorted by the presence of an intramural leiomyoma (1.0 x 0.8 x 0.6 cm) deep to the posterior side, near the left horn of the uterus. The myometrium has a maximum thickness of 0.9 cm. The serosal surface is unremarkable.

Micro 15 - anterior cervix, 1 frag,
Micro 16 - posterior cervix, 1 frag,
Micro 17 - posterior LUS, 1 frag,
Micro 18-19 - anterior endometrium, 2 frags,
Micro 20 - posterior endometrium, 1 frag,

Part 7, "tumor from cul de sac", consists of multiple fragments of firm, white/tan soft tissue (ranging in size from 0.6 x 0.4 x 0.2 cm up to 5.5 x 4.0 x 2.7 cm) with a diffusely hemorrhagic, granular surface. The tissue is grossly similar to that submitted in part 3.

Micro 21-22 - tumor from cul de sac, 2 frags,
Reports to:

SPECIMEN TYPE: TISSUE FOR SPECIAL STUDIES ONLY

ADDITIONAL SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: UTERUS WITH OR WITHOUT TUBES & OVARIES, NEOPLASTIC

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

Source: NCI Genomic Data Commons file d87e5b6a-3922-40a5-84c7-4fa074572bbb (TCGA-30-1861.446BE880-D1D8-4B63-B4D5-5AA0468CCAFE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).